Somatic mutation profile of cancer-model specimen HCM-BROD-0414-C25-85M (3D Organoid, passage 6; aliquot HCM-BROD-0414-C25-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0414-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 53.8 years (19,635 days).
Specimen HCM-BROD-0414-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3947ec9c-6639-402d-96cd-0a92b2deb3c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0414-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0414-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b084af5-ab06-4db5-8334-cfb7d09e6463

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Intron 2, Frame Shift Ins 1, RNA 1, 5'Flank 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 360/595 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 284/285 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ASB2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 765/765 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100279160; called by muse, mutect2, varscan2
- ASPM | c.5129A>G p.Q1710R | Missense Mutation (SNP) | VAF 103/462 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs1448167825; called by muse, mutect2, varscan2
- ATF7IP2 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 182/424 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs150059548; called by muse, mutect2, varscan2
- CCDC71L | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 278/583 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as rs1433621517; called by muse, mutect2, varscan2
- CCDC88A | c.2032dup p.T678Nfs*4 | Frame Shift Ins (INS) | VAF 62/202 reads (31%) | catalogued as rs750732366; called by mutect2, varscan2
- CDYL2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 294/639 reads (46%) | catalogued as rs766737973; called by muse, mutect2, varscan2
- COG7 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 320/682 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs768397627, COSV56150259; called by muse, mutect2, varscan2
- KATNAL1 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750176968; called by muse, mutect2, varscan2
- KCNT1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 355/951 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.428); catalogued as rs766377529; called by muse, mutect2, varscan2
- NFASC | c.1343C>T p.T448M (on ENST00000339876 / NM_001378329.1; = p.T459M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/533 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs536030954, COSV58370172; called by muse, mutect2, varscan2
- NPC1L1 | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 126/571 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as rs777474440, COSV56924034; called by muse, mutect2, varscan2
- NRROS | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 124/426 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs971980384, COSV60745001; called by muse, mutect2, varscan2
- OR4C13 | c.26A>C p.E9A | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1555015644, COSV73648609; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 403/888 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- PIK3IP1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99314011; called by muse, mutect2
- PSTPIP1 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 126/573 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1141042; called by muse, mutect2, varscan2
- SBK3 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 217/652 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362464318; called by muse, mutect2, varscan2
- SMC6 | c.2915A>G p.Q972R | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs1194643869; called by muse, mutect2, varscan2
- SPEG | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 91/860 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs778695872, COSV56664659; called by muse, mutect2, varscan2
- TAPBPL | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 211/214 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs769518478; called by muse, mutect2, varscan2
- TMEM176A | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 198/783 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs371746484; called by muse, mutect2, varscan2
- XIRP2 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.038); catalogued as rs942815960; called by muse, mutect2, varscan2
- AIRE | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 380/380 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CHCHD2 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 390/756 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COLGALT2 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 124/553 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- FCGR2B | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 195/445 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FREM3 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 76/572 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- IGSF10 | c.5269G>T p.V1757F | Missense Mutation (SNP) | VAF 126/377 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- METTL3 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 347/348 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MFHAS1 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 324/335 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- MPEG1 | c.1804A>C p.M602L | Missense Mutation (SNP) | VAF 231/502 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKX2-4 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 558/798 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, varscan2
- PAQR6 | c.509C>A p.S170Y (on ENST00000292291 / NM_001272108.2; = p.S64Y on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/543 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2G | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PRKCG | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 183/585 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRSS1 | c.142_156del p.C48_L52del | In Frame Del (DEL) | VAF 189/688 reads (27%) | called by pindel, varscan2
- ROBO2 | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TBC1D10B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 420/879 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by mutect2, varscan2
- TMEM151B | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 291/558 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TMTC1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 240/1552 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC17 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 308/653 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF503 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 36/768 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- AOPEP | c.2337C>A p.L779= (on ENST00000375315 / NM_001193329.1; = p.L680= on NM_032823.5) | Silent (SNP) | VAF 209/603 reads (35%) | called by muse, mutect2, varscan2
- EIF2B5 | c.600C>T p.H200= (on ENST00000647909; = p.H192= on NM_003907.3) | Silent (SNP) | VAF 160/491 reads (33%) | called by muse, mutect2, varscan2
- GABRG3 | c.1080C>T p.S360= | Silent (SNP) | VAF 388/390 reads (99%) | called by muse, mutect2, varscan2
- HDAC4 | c.1587C>T p.L529= | Silent (SNP) | VAF 482/733 reads (66%) | called by muse, mutect2, varscan2
- NOS2 | c.2703C>A p.P901= | Silent (SNP) | VAF 453/454 reads (100%) | called by muse, varscan2
- PAX1 | c.1218C>T p.A406= | Silent (SNP) | VAF 332/1084 reads (31%) | catalogued as rs761345173, COSV68272559; called by muse, varscan2
- PCDHGA6 | c.921A>G p.L307= | Silent (SNP) | VAF 129/556 reads (23%) | called by muse, mutect2, varscan2
- PXYLP1 | c.207C>T p.N69= | Silent (SNP) | VAF 252/376 reads (67%) | called by muse, mutect2, varscan2
- RBMXL2 | c.354G>A p.P118= | Silent (SNP) | VAF 301/626 reads (48%) | called by muse, mutect2, varscan2
- TAS1R2 | c.1161C>T p.S387= | Silent (SNP) | VAF 180/682 reads (26%) | catalogued as rs139739080, COSV64743807; called by muse, mutect2, varscan2
- TDRKH | c.429C>T p.G143= | Silent (SNP) | VAF 73/418 reads (17%) | catalogued as rs751347895; called by muse, mutect2, varscan2
- ATP8B2 | c.1133+48C>T | Intron (SNP) | VAF 122/509 reads (24%) | called by muse, mutect2, varscan2
- PLEKHG4B | chr5:139804 C>T | 5'Flank (SNP) | VAF 67/657 reads (10%) | called by muse, mutect2, varscan2
- SLC66A1L | n.498G>T | RNA (SNP) | VAF 187/286 reads (65%) | catalogued as rs964065892; called by muse, mutect2, varscan2
- TUBB8 | c.166+26G>A | Intron (SNP) | VAF 167/654 reads (26%) | catalogued as rs1250623817; called by muse, mutect2, varscan2
